CCDI case PBBRLH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/23635bac-1901-4f73-a5f1-05db6087bae6

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, poorly differentiated, with heterologous elements: ICD-O-3 morphology code: 8634/3; Tissue or organ of origin: Ovary; Age at diagnosis: 14.6 years (5,335 days).

Biospecimens (4 samples)
- Sample 0DFYPL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFYQ6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DFYQD, 0DG0G8 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
